Gene-level copy-number profile of tumor specimen TCGA-KK-A7B1-01A from TCGA case TCGA-KK-A7B1, project TCGA-PRAD (Prostate Adenocarcinoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Prostate gland; Age at diagnosis: 65.2 years (23,803 days).
Specimen TCGA-KK-A7B1-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-PRAD.a70903c7-3a47-4069-97f0-2154ab8696cd.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-KK-A7B1-11A (solid tissue normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 804 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/1ef9ba27-2215-44ed-ba97-67517a1e207c

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 0: 14; copy number 1: 4,016; copy number 2: 55,783; copy number 3: 6.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-KK-A7B1-01A-11D-A32A-01): tumor purity 0.54, ploidy 1.97, whole-genome doublings 0.

Homozygous deletions (total copy number 0; autosomes only): 14 genes in 1 contiguous region (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr3:32,151,083–32,635,554, 14 genes: AC094019.2, RPSAP11, AC097639.1, CMTM8, AC097639.2, KRT18P15, CMTM7, CMTM6, MIR548AY, AC104306.1, DYNC1LI1, AC104306.2, IGBP1P3, RPL30P4.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): none.

Autosomal genes at a single copy (total copy number 1): 1,635. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
